Gene-level copy-number profile of tumor specimen C3N-03921-02 from CPTAC case C3N-03921, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 73.1 years (26,682 days).
Specimen C3N-03921-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0c5a0d1b-5bed-45a8-b510-25ce7a8adf70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03921-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/a6041dd0-7434-4a23-b298-b7f96b06c40e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 89; copy number 1: 5,054; copy number 2: 21,704; copy number 3: 18,099; copy number 4: 11,539; copy number 5: 1,725; copy number 6: 42; copy number 7: 124; copy number 8: 27.

Homozygous deletions (total copy number 0; autosomes only): 89 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:25,754,925–25,755,670, 1 gene (within-gene range 0–2): TAF9BP1.
- chr15:85,380,596–85,415,633, 3 genes (within-gene range 0–1): MIR7706, RNU7-79P, FABP5P9.
- chr18:59,929,226–59,930,330, 1 gene: AC107990.1.
- chr21:13,581,060–16,645,467, 69 genes (broad region; genes not listed).
- chr22:27,748,277–28,679,865, 15 genes (within-gene range 0–2): MN1, PITPNB, TTC28-AS1, AL031591.2, MIR3199-1, MIR3199-2, AL031591.1, TTC28, AL033538.1, AL033538.2, RN7SL757P, SNORD42, Y_RNA, MIR5739, RN7SL162P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,917 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,419,625–145,281,462, 65 genes, copy number 5–7 (broad region; genes not listed).
- chr5:45,890,216–52,959,209, 32 genes, copy number 5–6 (within-gene range 4–6): AC122694.1, EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2.
- chr7:143,183,419–159,233,377, 326 genes, copy number 5–7 (broad region; genes not listed).
- chr8:144,827,464–145,066,685, 11 genes, copy number 5: ZNF7, COMMD5, ZNF250, ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:42,817,105–42,823,213, 1 gene, copy number 5: MEP1AP4.
- chr14:18,333,726–19,830,253, 75 genes, copy number 5–8 (broad region; genes not listed).
- chr16:11,555–35,912,516, 1,407 genes, copy number 5–7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,054. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
